Somatic mutation profile of tumor specimen MMRF_1890_1_BM_CD138pos (aliquot MMRF_1890_1_BM_CD138pos_T1_KBS5U_L05558) from MMRF case MMRF_1890, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.8 years (17,444 days).
Specimen MMRF_1890_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11d85010-c3a5-48c5-8665-4e3df7acfb17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1890_2_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1890_2_PB_CD3pos_C1_KBS5U_L05562; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7c9b58e-62cf-4125-8069-9669e0d55c5a

The open-access MAF lists 90 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 27, Intron 10, Silent 8, 5'UTR 7, RNA 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 14/99 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs1057520008, CD100447, COSV52760580, COSV52806341, COSV52877975, COSV52979708; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, varscan2
- ABCB5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs372984477; called by muse, mutect2, varscan2
- ALDH1L1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1259689090; called by muse, mutect2, varscan2
- CACHD1 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs182391558, COSV51547812; called by muse, varscan2
- DMD | c.8988T>A p.N2996K | Missense Mutation (SNP) | VAF 59/68 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58907649; called by muse, mutect2, varscan2
- EPHA5 | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 93/106 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs547306138; called by muse, mutect2, varscan2
- FGFR3 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104368257; called by muse, mutect2
- GSAP | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV99990588; called by muse, mutect2, varscan2
- MDGA2 | c.2724C>A p.F908L (on ENST00000399232 / NM_001113498.2; = p.F610L on NM_182830.4) | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV62085136; called by muse, varscan2
- MKI67 | c.4360C>T p.H1454Y | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1419637759; called by muse, mutect2
- OR8A1 | c.184T>C p.F62L | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.32); catalogued as rs202194717; called by muse, mutect2, varscan2
- PARP10 | c.606del p.L204Wfs*38 | Frame Shift Del (DEL) | VAF 26/257 reads (10%) | catalogued as rs782379603; called by mutect2, pindel, varscan2
- SPATA13 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV66067605; called by muse, mutect2, varscan2
- TBL1XR1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101467747; called by muse, mutect2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 70/86 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, varscan2
- TRMT61B | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs371841780; called by muse, mutect2
- WDR83 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as rs766475506; called by muse, mutect2, varscan2
- ZNF615 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs775848108; called by muse, mutect2, varscan2
- ZNF737 | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1568425610; called by muse, mutect2, varscan2
- CDYL | c.310G>C p.E104Q (on ENST00000328908 / NM_001368125.1; = p.E50Q on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/725 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- CORIN | c.1812C>A p.D604E | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERBB3 | c.2090A>G p.N697S | Missense Mutation (SNP) | VAF 24/24 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HHIPL2 | c.1568T>A p.F523Y | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- IGKV2-30 | c.268A>G p.S90G | Missense Mutation (SNP) | VAF 72/190 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, varscan2
- LTB | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.13178C>A p.A4393D | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OVCH1 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PADI1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKDC | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRM | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PZP | c.2836G>C p.V946L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SUZ12 | c.1012C>T p.L338F | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.888); called by muse, mutect2
- TET1 | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF735 | c.467T>G p.I156R | Missense Mutation (SNP) | VAF 75/89 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- DCLK1 | c.1008C>T p.T336= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- DUS3L | c.1668C>T p.Y556= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs780286044, COSV57831287; called by muse, mutect2, varscan2
- FMN2 | c.4101A>T p.A1367= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100142860, COSV100144048; called by muse, mutect2, varscan2
- GRIA2 | c.1449G>A p.G483= | Silent (SNP) | VAF 9/116 reads (8%) | catalogued as COSV52392170, COSV99646103; called by muse, mutect2
- KMT2B | c.6117G>A p.V2039= | Silent (SNP) | VAF 10/187 reads (5%) | catalogued as COSV55860578; called by muse, mutect2
- OR4F15 | c.327C>T p.G109= | Silent (SNP) | VAF 12/159 reads (8%) | catalogued as rs1204983572, COSV59968956; called by muse, mutect2
- PDS5A | c.1782C>T p.A594= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- TOR4A | c.888C>T p.Y296= | Silent (SNP) | VAF 104/199 reads (52%) | catalogued as rs762976423; called by muse, mutect2, varscan2
- AP005242.2 | n.142C>T | RNA (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- ARL14EP | c.*32G>A | 3'UTR (SNP) | VAF 6/86 reads (7%) | catalogued as rs948456127; called by muse, mutect2
- BROX | c.-173G>A | 5'UTR (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- C11orf80 | c.-114C>T | 5'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CETN2 | c.*750T>A | 3'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- CLK1 | c.-85T>A | 5'UTR (SNP) | VAF 22/23 reads (96%) | called by muse, mutect2, varscan2
- CNNM1 | c.2176+3548G>A | Intron (SNP) | VAF 116/298 reads (39%) | catalogued as rs1318440364; called by mutect2, varscan2
- COBL | c.*195_*197del | 3'UTR (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- CPNE3 | c.*223A>G | 3'UTR (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- CRISPLD2 | c.359+35G>C | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- FNIP1 | c.*952G>A | 3'UTR (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- FNIP1 | c.*787A>G | 3'UTR (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- GPR132 | c.-319G>T | 5'UTR (SNP) | VAF 41/81 reads (51%) | catalogued as rs901919132; called by muse, mutect2, varscan2
- HS2ST1 | c.-254G>A | 5'UTR (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- HYDIN2 | n.9607C>T | RNA (SNP) | VAF 75/150 reads (50%) | called by muse, varscan2
- IL17RD | c.*2957A>G | 3'UTR (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- LINC01621 | n.1231G>A | RNA (SNP) | VAF 19/28 reads (68%) | catalogued as rs993259778; called by muse, mutect2, varscan2
- LRIT2 | c.*627G>A | 3'UTR (SNP) | VAF 91/169 reads (54%) | called by muse, mutect2, varscan2
- MMP16 | c.*5680T>G | 3'UTR (SNP) | VAF 73/105 reads (70%) | called by muse, mutect2, varscan2
- MOB3B | c.*492T>A | 3'UTR (SNP) | VAF 12/55 reads (22%) | called by mutect2, varscan2
- MPPED2 | c.*2749C>T | 3'UTR (SNP) | VAF 29/346 reads (8%) | catalogued as rs764289411; called by muse, mutect2
- NTRK3 | c.*9108T>A | 3'UTR (SNP) | VAF 54/131 reads (41%) | called by muse, mutect2, varscan2
- OR51F2 | c.-8G>T | 5'UTR (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- OTOR | c.*358G>A | 3'UTR (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- PAK1 | c.*644G>T | 3'UTR (SNP) | VAF 63/124 reads (51%) | called by muse, mutect2, varscan2
- PCNX1 | c.*2092T>A | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- PFKFB1 | c.*321C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | catalogued as rs1023176093; called by muse, mutect2
- PFN2 | c.*134C>T | 3'UTR (SNP) | VAF 66/506 reads (13%) | called by muse, mutect2, varscan2
- PHACTR1 | c.1447+1359C>G | Intron (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- PPP1R14C | c.*1234G>T | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-281G>A | Intron (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- RC3H1 | c.*2814C>T | 3'UTR (SNP) | VAF 6/151 reads (4%) | called by muse, mutect2
- RPL15 | c.309+126T>C | Intron (SNP) | VAF 10/45 reads (22%) | called by mutect2, varscan2
- RRAGA | c.-100G>A | 5'UTR (SNP) | VAF 78/135 reads (58%) | called by muse, mutect2, varscan2
- SDR16C6P | n.673G>A | RNA (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2
- SLC2A1 | c.*409A>G | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- SLC47A2 | c.123+32A>T | Intron (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- SPATA6 | c.487-1234G>A | Intron (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- STK32A | c.*1972C>T | 3'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- SUV39H2 | c.850-650T>A | Intron (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- TEKT4 | c.499-572G>A | Intron (SNP) | VAF 19/119 reads (16%) | catalogued as rs1553395108; called by muse, mutect2, varscan2
- TENM4 | c.*3434A>G | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- TIAM1 | c.2217+118C>T | Intron (SNP) | VAF 4/15 reads (27%) | catalogued as rs866639703; called by mutect2, varscan2
- TIMM50 | c.*102_*110del | 3'UTR (DEL) | VAF 11/70 reads (16%) | called by mutect2, pindel, varscan2
- UBA5 | c.*479C>A | 3'UTR (SNP) | VAF 47/120 reads (39%) | called by muse, mutect2, varscan2
- USP31 | c.*5516A>G | 3'UTR (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- WDR70 | c.*273T>A | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZC3HC1 | c.*349G>A | 3'UTR (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
